Somatic mutation profile of tumor specimen HCM-WCMC-0786-C34-01A (aliquot HCM-WCMC-0786-C34-01A-20D-A87L-36) from HCMI case HCM-WCMC-0786-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 76.8 years (28,050 days).
Specimen HCM-WCMC-0786-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88c1abff-5b0b-4c5a-a9a6-c41966a376ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0786-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0786-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1112a6ed-a997-4549-a8f3-6a0c3e2d78dd

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 18, Nonsense Mutation 5, Frame Shift Del 3, 3'UTR 1, Intron 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 146/688 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 38/200 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BPIFB2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1228059077; called by muse, mutect2
- C2orf16 | c.4609A>G p.K1537E | Missense Mutation (SNP) | VAF 74/466 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.95); catalogued as rs1463877280; called by muse, mutect2, varscan2
- CDC42BPG | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs149057251; called by muse, mutect2, varscan2
- DCAF4L2 | c.659C>A p.S220* | Nonsense Mutation (SNP) | VAF 53/461 reads (11%) | catalogued as COSV60478060; called by muse, mutect2, varscan2
- DIO3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 65/298 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as rs370365050; called by muse, mutect2, varscan2
- DISP3 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199823398, COSV53839940; called by muse, mutect2, varscan2
- EML3 | c.1334C>A p.T445N | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53904596; called by muse, mutect2, varscan2
- ETNPPL | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 61/520 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.595); catalogued as rs765723050; called by muse, mutect2, varscan2
- FAM47A | c.1072G>T p.G358* | Nonsense Mutation (SNP) | VAF 91/287 reads (32%) | catalogued as COSV100649780; called by muse, mutect2, varscan2
- MBD3L3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 67/869 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1196514778; called by muse, mutect2
- MEPE | c.806G>T p.G269V | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63071884; called by muse, mutect2, varscan2
- MTMR10 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 40/346 reads (12%) | catalogued as rs753837494; called by muse, mutect2, varscan2
- MUC12 | c.13460C>T p.T4487I (on ENST00000379442; = p.T4344I on NM_001164462.1) | Missense Mutation (SNP) | VAF 54/1557 reads (3%) | SIFT tolerated, low confidence (0.08); catalogued as rs1315652498; called by muse, mutect2
- MXRA5 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756893962, COSV54242793; called by muse, mutect2, varscan2
- NKX2-1 | c.392del p.P131Rfs*5 | Frame Shift Del (DEL) | VAF 43/297 reads (14%) | catalogued as COSV61389589; called by pindel, varscan2
- NOVA1 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 40/750 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57473964; called by muse, mutect2
- PPP1R26 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 74/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs753775579, COSV100778043; called by muse, mutect2, varscan2
- SBNO2 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 64/365 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs762056811; called by muse, mutect2, varscan2
- SCN7A | c.222C>A p.Y74* | Nonsense Mutation (SNP) | VAF 31/301 reads (10%) | catalogued as rs1352909992; called by mutect2, varscan2
- SORL1 | c.6560C>T p.S2187F | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52764030; called by muse, mutect2, varscan2
- SPARCL1 | c.1679T>G p.I560S | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56805012; called by muse, mutect2, varscan2
- A2ML1 | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANKRD30A | c.2801A>T p.Q934L (on ENST00000611781; = p.Q878L on NM_052997.2) | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ARFGEF1 | c.3928G>A p.E1310K | Missense Mutation (SNP) | VAF 29/549 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2
- BIRC6 | c.6365_6372del p.S2122Wfs*6 | Frame Shift Del (DEL) | VAF 18/184 reads (10%) | called by pindel, varscan2
- BIRC6 | c.6376C>T p.Q2126* | Nonsense Mutation (SNP) | VAF 22/203 reads (11%) | called by muse, varscan2
- DCDC2C | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLRE1A | c.1700C>G p.P567R | Missense Mutation (SNP) | VAF 86/635 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMAC2L | c.76T>G p.F26V | Missense Mutation (SNP) | VAF 70/443 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ELL2 | c.1349C>G p.P450R | Missense Mutation (SNP) | VAF 65/550 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- FLI1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 107/543 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.3035C>A p.P1012H | Missense Mutation (SNP) | VAF 64/410 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GADL1 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IGLV2-8 | c.165del p.W56Gfs*13 | Frame Shift Del (DEL) | VAF 71/479 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.3532A>C p.N1178H | Missense Mutation (SNP) | VAF 27/855 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- NKX2-1 | c.442dup p.D148Gfs*261 | Frame Shift Ins (INS) | VAF 62/383 reads (16%) | called by pindel, varscan2
- OR4E2 | c.363T>A p.D121E | Missense Mutation (SNP) | VAF 84/606 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R18 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 61/562 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- PROSER2 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- RAB40A | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 106/335 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- UBASH3A | c.746T>A p.L249Q | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR74 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- WNK2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 72/367 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZC3H7B | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARAP2 | c.4857G>A p.K1619= | Silent (SNP) | VAF 114/741 reads (15%) | catalogued as COSV58284361; called by muse, mutect2, varscan2
- BAIAP2L2 | c.585C>T p.S195= | Silent (SNP) | VAF 51/280 reads (18%) | catalogued as rs750948908; called by muse, mutect2, varscan2
- CDC42EP3 | c.552C>T p.G184= | Silent (SNP) | VAF 73/525 reads (14%) | called by muse, mutect2, varscan2
- CHD8 | c.1293A>G p.S431= (on ENST00000646647 / NM_001170629.2; = p.S152= on NM_020920.4) | Silent (SNP) | VAF 76/464 reads (16%) | called by muse, mutect2, varscan2
- CYP26C1 | c.498G>A p.R166= | Silent (SNP) | VAF 46/283 reads (16%) | called by muse, mutect2, varscan2
- DYRK2 | c.1380T>G p.G460= (on ENST00000344096 / NM_006482.3; = p.G387= on NM_003583.4) | Silent (SNP) | VAF 70/453 reads (15%) | called by muse, mutect2, varscan2
- FLNC | c.3036C>A p.P1012= | Silent (SNP) | VAF 65/411 reads (16%) | catalogued as COSV57964752; called by muse, mutect2, varscan2
- FTMT | c.102G>T p.P34= | Silent (SNP) | VAF 64/316 reads (20%) | catalogued as rs1428528606, COSV100360441; called by muse, mutect2, varscan2
- GPM6A | c.771G>A p.K257= | Silent (SNP) | VAF 120/716 reads (17%) | called by muse, mutect2, varscan2
- NBEA | c.1222T>C p.L408= | Silent (SNP) | VAF 72/464 reads (16%) | called by muse, mutect2, varscan2
- OPRM1 | c.702G>T p.L234= | Silent (SNP) | VAF 97/686 reads (14%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1170G>A p.T390= | Silent (SNP) | VAF 41/322 reads (13%) | catalogued as COSV65346327; called by muse, mutect2, varscan2
- PERCC1 | c.534C>T p.F178= | Silent (SNP) | VAF 47/281 reads (17%) | catalogued as rs533074405; called by muse, mutect2, varscan2
- PLXNA1 | c.141C>T p.S47= | Silent (SNP) | VAF 18/358 reads (5%) | catalogued as rs781271756; called by muse, mutect2
- SLC6A3 | c.1266C>T p.S422= | Silent (SNP) | VAF 37/237 reads (16%) | catalogued as rs1246818027, COSV54364542, COSV54366912; called by muse, mutect2, varscan2
- TEKT3 | c.804C>T p.D268= | Silent (SNP) | VAF 84/547 reads (15%) | catalogued as rs149266687; called by muse, mutect2, varscan2
- TENM3 | c.7872G>A p.A2624= | Silent (SNP) | VAF 29/191 reads (15%) | catalogued as rs367925910; called by muse, mutect2, varscan2
- TULP4 | c.1596A>G p.K532= | Silent (SNP) | VAF 57/348 reads (16%) | called by muse, mutect2, varscan2
- NPAP1L | n.29C>T | RNA (SNP) | VAF 41/257 reads (16%) | catalogued as rs1488657661; called by muse, mutect2, varscan2
- PHACTR1 | c.1650+40G>A | Intron (SNP) | VAF 28/115 reads (24%) | catalogued as rs771796074; called by muse, mutect2, varscan2
- WDR26 | c.*128T>C | 3'UTR (SNP) | VAF 85/748 reads (11%) | called by muse, mutect2, varscan2
